CPTAC case C3L-02549 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8353437c-ec0a-4fca-b619-74e6c4e5b375

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1947; Vital status: Dead; Days to death: 447 days (1.2 years); Year of death: 2018; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 69.7 years (25,447 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 447 days (1.2 years); Progression or recurrence: yes; Days to recurrence: 216 days; Days to last follow up: 447 days (1.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 12 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 17; Margin status: Uninvolved.

Follow-up (3 entries)
- Days to follow up: 341 days; Disease response: With Tumor.
- Days to follow up: 447 days (1.2 years); Disease response: With Tumor.
- Days to follow up: 447 days (1.2 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 216 days.

Other clinical attributes
- Weight: 96 kg; Height: 180 cm; BMI: 29.63.

Exposures
- Tobacco smoking status: Current Smoker; Alcohol history: Yes; Alcohol intensity: Heavy Drinker.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02549-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 715 mg.
- Sample C3L-02549-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 739 mg; Time between excision and freezing: 25 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02549-22: Section location: Left Lower Lobe; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3L-02549-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 209 mg; Time between excision and freezing: 25 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02549-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
- Sample C3L-02549-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
